Somatic mutation profile of tumor specimen ALCH-ABZ1-TTP1-A (aliquot ALCH-ABZ1-TTP1-A-1-0-D-A491-36) from ALCHEMIST case ALCH-ABZ1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.9 years (25,172 days).
Specimen ALCH-ABZ1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bbc6f99-11b5-48b0-8653-5305150452e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABZ1-NB1-A (Blood Derived Normal), aliquot ALCH-ABZ1-NB1-A-1-0-D-A491-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6a8fee8-db23-41b2-b49a-ba19667d849b

The open-access MAF lists 80 somatic variants for this specimen: 46 protein-altering or splice-affecting, 26 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 26, Intron 5, Nonsense Mutation 4, 5'UTR 1, Splice Region 1, RNA 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 335/1085 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AGMO | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 92/349 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs144754984; called by muse, mutect2, varscan2
- ARHGAP4 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 99/531 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs782276308; called by muse, mutect2, varscan2
- C6orf118 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs1049340242; called by muse, mutect2, varscan2
- DNAH14 | c.1873G>A p.D625N (on ENST00000445597; = p.D654N on NM_001367479.1) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1274192513; called by mutect2, varscan2
- FPR3 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as rs146700831; called by muse, mutect2, varscan2
- FSIP2 | c.20134T>A p.F6712I | Missense Mutation (SNP) | VAF 22/576 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs928129379, COSV58085601; called by muse, mutect2
- H2AZ2 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 140/500 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as rs1324869868; called by muse, mutect2, varscan2
- KPRP | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as rs1403896561, COSV64221515; called by muse, mutect2
- MAGEB1 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as rs1306878364, COSV100974834; called by muse, mutect2
- MARF1 | c.4238G>T p.R1413L | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60021678; called by muse, mutect2, varscan2
- MYO1A | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs200450661; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEU2 | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.608); catalogued as rs747118643, COSV52092991; called by muse, mutect2, varscan2
- PLXNB3 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs781889794; called by muse, mutect2, varscan2
- RSBN1L | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs762959199, COSV58506405; called by muse, mutect2, varscan2
- RYR1 | c.10492C>T p.R3498C | Missense Mutation (SNP) | VAF 211/442 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs201358408, COSV62109595; called by muse, mutect2, varscan2
- SAGE1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1388913769, COSV61016705; called by muse, mutect2, varscan2
- SYBU | c.302T>G p.I101S (on ENST00000276646 / NM_001099754.2; = p.I100S on NM_017786.6) | Missense Mutation (SNP) | VAF 248/488 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs767020635; called by muse, mutect2, varscan2
- VNN1 | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs776994718; called by muse, mutect2, varscan2
- ZNF536 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 27/361 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs144763919; called by muse, mutect2
- ZNF728 | c.485G>T p.R162I | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1037862372; called by muse, mutect2
- ABCC9 | c.4256G>T p.W1419L | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFAP1L1 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2
- CBLB | c.2602C>T p.P868S | Missense Mutation (SNP) | VAF 30/639 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDH2 | c.1709T>C p.I570T | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- DVL1 | c.1853A>T p.E618V (on ENST00000378888 / NM_001330311.2; = p.E593V on NM_004421.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DVL1 | c.604A>T p.R202W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FANCD2 | c.4015C>T p.H1339Y | Missense Mutation (SNP) | VAF 42/608 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLG | c.4427G>A p.S1476N | Missense Mutation (SNP) | VAF 239/1168 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FRMPD2B | n.857A>G | Splice Region (SNP) | VAF 89/695 reads (13%) | called by muse, mutect2, varscan2
- FRY | c.3835C>G p.Q1279E | Missense Mutation (SNP) | VAF 20/704 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- GUCY1B1 | c.671A>T p.D224V | Missense Mutation (SNP) | VAF 158/341 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LPAR6 | c.705G>C p.L235F | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- LRP2 | c.8095C>T p.R2699* | Nonsense Mutation (SNP) | VAF 249/619 reads (40%) | called by muse, mutect2, varscan2
- MED13 | c.1178_1181dup p.Y394* | Nonsense Mutation (INS) | VAF 46/231 reads (20%) | called by mutect2, pindel, varscan2
- MEOX2 | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 127/451 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- MFSD10 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 213/509 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- PKDREJ | c.3040T>C p.Y1014H | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PKHD1L1 | c.10400A>C p.Q3467P | Missense Mutation (SNP) | VAF 123/286 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- RGPD2 | c.4073G>A p.R1358K | Missense Mutation (SNP) | VAF 38/1300 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2
- SPTBN4 | c.3593C>A p.A1198E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SPTLC1 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 114/532 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TP53 | c.795_814del p.G266Afs*33 | Frame Shift Del (DEL) | VAF 235/813 reads (29%) | called by mutect2, pindel, varscan2
- UNC13C | c.3748G>C p.G1250R | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP20 | c.6308C>T p.S2103L | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2
- VWF | c.5026C>A p.Q1676K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM22 | c.2133C>T p.C711= | Silent (SNP) | VAF 38/347 reads (11%) | catalogued as COSV55969022; called by muse, mutect2, varscan2
- ADGRB1 | c.651C>A p.G217= | Silent (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- AK8 | c.1263C>T p.N421= | Silent (SNP) | VAF 75/347 reads (22%) | catalogued as rs1294723393; called by muse, mutect2, varscan2
- ANK2 | c.3006G>A p.T1002= | Silent (SNP) | VAF 112/488 reads (23%) | catalogued as rs181534986; called by muse, mutect2, varscan2
- ATF4 | c.483A>G p.Q161= | Silent (SNP) | VAF 82/213 reads (38%) | catalogued as rs767949359; called by muse, mutect2, varscan2
- BTD | c.789G>A p.E263= | Silent (SNP) | VAF 48/377 reads (13%) | catalogued as COSV100329398; called by muse, mutect2, varscan2
- CDHR4 | c.1095G>A p.P365= | Silent (SNP) | VAF 58/495 reads (12%) | catalogued as rs370686742; called by muse, mutect2, varscan2
- CDS2 | c.1134C>T p.G378= | Silent (SNP) | VAF 92/265 reads (35%) | called by muse, mutect2, varscan2
- CFAP46 | c.240C>A p.T80= | Silent (SNP) | VAF 84/192 reads (44%) | called by muse, mutect2, varscan2
- CFAP94 | c.1620C>T p.I540= (on ENST00000320267 / NM_001352064.2; = p.I546= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/353 reads (4%) | called by muse, mutect2
- CSPP1 | c.3099G>A p.L1033= (on ENST00000676605; = p.L992= on NM_024790.6) | Silent (SNP) | VAF 96/267 reads (36%) | called by muse, mutect2, varscan2
- GATA3 | c.1263G>A p.P421= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as rs541782074, COSV60518783, COSV60519740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMNA | c.1335G>T p.V445= | Silent (SNP) | VAF 59/814 reads (7%) | called by muse, mutect2
- MSLNL | c.813G>A p.S271= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as rs374819779; called by muse, mutect2, varscan2
- MYH10 | c.2529G>A p.P843= | Silent (SNP) | VAF 100/496 reads (20%) | catalogued as rs1339221553; called by muse, mutect2, varscan2
- NHS | c.4821A>G p.A1607= | Silent (SNP) | VAF 355/1275 reads (28%) | called by muse, mutect2, varscan2
- PABPC4 | c.687A>G p.K229= | Silent (SNP) | VAF 68/411 reads (17%) | called by muse, mutect2, varscan2
- PCDHB16 | c.810C>T p.D270= | Silent (SNP) | VAF 48/281 reads (17%) | catalogued as COSV53364859; called by muse, mutect2, varscan2
- PCDHGA1 | c.1536G>T p.G512= | Silent (SNP) | VAF 14/141 reads (10%) | catalogued as rs1285141627; called by muse, mutect2, varscan2
- SATB1 | c.492C>T p.V164= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs768455394; called by muse, mutect2, varscan2
- SMG1 | c.3417C>A p.I1139= | Silent (SNP) | VAF 48/392 reads (12%) | called by muse, mutect2, varscan2
- THBS2 | c.2016C>T p.S672= | Silent (SNP) | VAF 20/722 reads (3%) | called by muse, mutect2
- TNXB | c.8295G>A p.G2765= (on ENST00000647633; = p.G2518= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as rs768743709; called by muse, mutect2, varscan2
- USP5 | c.2337A>G p.S779= (on ENST00000229268 / NM_001098536.2; = p.S756= on NM_003481.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 67/191 reads (35%) | called by muse, mutect2, varscan2
- ZNF185 | c.2013G>A p.Q671= | Silent (SNP) | VAF 74/437 reads (17%) | called by muse, mutect2, varscan2
- ZNF555 | c.975G>A p.S325= | Silent (SNP) | VAF 68/357 reads (19%) | catalogued as rs565200366; called by muse, mutect2, varscan2
- ADAM32 | c.139-6600T>C | Intron (SNP) | VAF 2/11 reads (18%) | called by muse, mutect2
- CARS1 | c.26-5640C>T | Intron (SNP) | VAF 29/295 reads (10%) | called by muse, mutect2, varscan2
- HEATR9 | c.454-9G>A | Intron (SNP) | VAF 26/120 reads (22%) | called by muse, varscan2
- MIR412 | n.67C>T | RNA (SNP) | VAF 42/517 reads (8%) | catalogued as rs775386036; called by muse, mutect2
- PIK3CD | c.-138+2469A>T | Intron (SNP) | VAF 88/1350 reads (7%) | called by muse, mutect2
- RAD51C | c.705+3223G>C | Intron (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
- SECISBP2 | c.-76G>A | 5'UTR (SNP) | VAF 13/170 reads (8%) | catalogued as rs1407315694; called by muse, mutect2
- ZNF213 | chr16:3145926 C>T | 3'Flank (SNP) | VAF 28/153 reads (18%) | catalogued as rs754001921; called by muse, mutect2, varscan2
